Gene-level copy-number profile of tumor specimen CUPP-B49D-TTM1-A from CCG case CUPP-B49D, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 43.6 years (15,935 days).
Specimen CUPP-B49D-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18c773b7-0e00-4df3-9b64-16d276df6674.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B49D-NT1-A (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/77ba9214-67c5-40e9-83a9-1c797a5cf868

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 2,937; copy number 2: 55,831; copy number 3: 29; copy number 4: 16; copy number 5: 41; copy number 6: 16; copy number 9: 1; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:186,771,841–186,773,476, 2 genes (within-gene range 0–2): RNU6-1105P, GPS2P2.
- chr16:32,439,069–32,441,159, 1 gene: PABPC1P13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:24,126,186–24,154,900, 1 gene, copy number 6: NRSN1.
- chr7:7,066,964–7,067,045, 1 gene, copy number 11: MIR3683.
- chr7:116,524,994–117,715,971, 40 genes, copy number 5 (within-gene range 4–5): CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1.
- chr7:154,928,460–155,223,851, 14 genes, copy number 6: PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.4.
- chr8:144,522,388–144,529,132, 2 genes, copy number 11 (within-gene range 2–11): LRRC24, C8orf82.
- chr16:2,660,348–2,682,379, 1 gene, copy number 9: ERVK13-1.

Autosomal genes at a single copy (total copy number 1): 138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
